Somatic mutation profile of tumor specimen C3N-03480-01 (aliquot CPT0285090006) from CPTAC case C3N-03480, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.0 years (21,561 days).
Specimen C3N-03480-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4586a0e-69c0-4cf4-a33a-5ef3348c0172.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03480-31 (Blood Derived Normal), aliquot CPT0285120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4546ef5-449e-49a4-b63d-f5d0b4ed9ef4

The open-access MAF lists 54 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, Splice Site 4, Intron 3, Splice Region 2, Nonsense Mutation 2, RNA 2, Frame Shift Del 2, 5'Flank 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 10/28 reads (36%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 444/680 reads (65%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGBL1 | c.3124C>G p.L1042V | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754862005; called by muse, mutect2, varscan2
- C8B | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 215/582 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs374321085; called by muse, mutect2, varscan2
- CHI3L1 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 71/723 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1311129415; called by muse, mutect2, varscan2
- CNTN2 | c.2738G>T p.R913L | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100085631; called by muse, mutect2, varscan2
- DLEC1 | c.2788G>T p.D930Y | Missense Mutation (SNP) | VAF 29/423 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs1438865670; called by muse, mutect2
- FRZB | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as COSV54554832; called by muse, mutect2, varscan2
- LAMC3 | c.4337C>T p.A1446V | Missense Mutation (SNP) | VAF 524/1219 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs745579219; called by muse, mutect2, varscan2
- PIK3R1 | c.1738T>G p.Y580D (on ENST00000521381 / NM_181523.3; = p.Y310D on NM_181504.4) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57124929, COSV57131742; called by muse, mutect2, varscan2
- RANBP17 | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs139703890; called by muse, mutect2, varscan2
- SCAF8 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 109/295 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1440123247; called by muse, mutect2, varscan2
- TCHHL1 | c.2189C>G p.A730G | Missense Mutation (SNP) | VAF 97/218 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.307); catalogued as rs745701503, COSV100916611; called by muse, mutect2, varscan2
- TGFBR2 | c.1255-4A>G | Splice Region (SNP) | VAF 168/329 reads (51%) | catalogued as rs773834537; called by muse, mutect2, varscan2
- TSHZ3 | c.157G>C p.A53P | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53683169; called by muse, mutect2, varscan2
- ZNF860 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770808631; called by muse, mutect2, varscan2
- AHNAK | c.15754G>A p.G5252R | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CA3 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.11116G>A p.E3706K | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2
- DNASE1L3 | c.447C>A p.F149L | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DUOX2 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- EEA1 | c.3931_3956del p.T1311Afs*3 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | called by mutect2, pindel
- EEF1B2 | c.81G>A p.G27= | Splice Region (SNP) | VAF 11/299 reads (4%) | called by muse, mutect2
- GINS2 | c.432+2T>C p.X144_splice | Splice Site (SNP) | VAF 63/136 reads (46%) | called by muse, mutect2, varscan2
- LMF2 | c.1023G>A p.W341* | Nonsense Mutation (SNP) | VAF 191/301 reads (63%) | called by muse, mutect2, varscan2
- LRRC20 | c.337C>G p.P113A (on ENST00000355790 / NM_207119.3; = p.P63A on NM_018239.4) | Missense Mutation (SNP) | VAF 197/331 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MACF1 | c.3286-1G>C p.X1096_splice | Splice Site (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- NIM1K | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NTN4 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2
- PDE11A | c.166G>C p.A56P | Missense Mutation (SNP) | VAF 75/669 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PGM3 | c.1129-1G>A p.X377_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | called by mutect2, varscan2
- PHLPP2 | c.1075_1077del p.T359del | In Frame Del (DEL) | VAF 21/64 reads (33%) | called by pindel, varscan2
- PKDREJ | c.5874C>A p.D1958E | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, varscan2
- PTEN | c.34_40del p.N12Gfs*10 | Frame Shift Del (DEL) | VAF 127/254 reads (50%) | called by mutect2, pindel, varscan2
- SENP3 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SLC2A12 | c.1346T>G p.I449R | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.285); called by muse, mutect2
- CCDC130 | c.78C>T p.Y26= | Silent (SNP) | VAF 13/348 reads (4%) | called by muse, mutect2
- CPNE7 | c.1758C>A p.L586= | Silent (SNP) | VAF 61/135 reads (45%) | called by muse, mutect2, varscan2
- CRP | c.642C>T p.G214= | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as rs776340499, COSV54813765; called by muse, mutect2, varscan2
- GDF6 | c.645C>T p.F215= | Silent (SNP) | VAF 29/214 reads (14%) | called by muse, mutect2, varscan2
- GYPC | c.45C>T p.S15= | Silent (SNP) | VAF 60/634 reads (9%) | called by muse, mutect2
- HOGA1 | c.738G>C p.L246= | Silent (SNP) | VAF 18/404 reads (4%) | catalogued as rs1433024862; called by muse, mutect2
- KCNN2 | c.1395A>G p.V465= (on ENST00000264773; = p.V677= on NM_021614.4) | Silent (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- MITF | c.540C>T p.P180= (on ENST00000448226 / NM_006722.3; = p.P74= on NM_000248.4) | Silent (SNP) | VAF 93/372 reads (25%) | catalogued as rs1391724046; called by muse, mutect2, varscan2
- NEU4 | c.942C>T p.H314= (on ENST00000391969 / NM_001167602.3; = p.H326= on NM_080741.4) | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as rs778804876, COSV57991261; called by muse, mutect2
- NR2C1 | c.1407A>G p.T469= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- AC106795.1 | n.631G>A | RNA (SNP) | VAF 50/196 reads (26%) | catalogued as rs1156398258; called by muse, mutect2, varscan2
- GDF1 | c.-24C>T | 5'UTR (SNP) | VAF 31/372 reads (8%) | catalogued as rs1039277212; called by muse, mutect2
- NEB | c.11601+6085C>T | Intron (SNP) | VAF 269/2243 reads (12%) | called by muse, mutect2, varscan2
- NKX2-1 | chr14:36520088 G>C | 5'Flank (SNP) | VAF 74/204 reads (36%) | called by muse, varscan2
- NKX2-1 | chr14:36520089 G>C | 5'Flank (SNP) | VAF 78/210 reads (37%) | catalogued as COSV61390045; called by muse, varscan2
- RABL6 | c.705+1587T>A | Intron (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- RALGPS1 | c.216+12214A>C | Intron (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
- SNORD116-24 | n.89G>C | RNA (SNP) | VAF 83/204 reads (41%) | called by muse, mutect2, varscan2
